Somatic mutation profile of tumor specimen ALCH-ADI1-TTP1-A (aliquot ALCH-ADI1-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADI1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.2 years (24,545 days).
Specimen ALCH-ADI1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c3bf093-6b39-418f-b380-0f81d63dea7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADI1-NB1-A (Blood Derived Normal), aliquot ALCH-ADI1-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5a76289-7d95-465e-84f3-0d2bbae4ec84

The open-access MAF lists 69 somatic variants for this specimen: 44 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Nonsense Mutation 3, Intron 3, 3'UTR 3, 5'UTR 2, Splice Region 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.8005G>T p.G2669C | Missense Mutation (SNP) | VAF 46/1324 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs794728281, CM154865; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 54/774 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2
- ADAMTSL1 | c.4778C>T p.A1593V | Missense Mutation (SNP) | VAF 38/1461 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.312); catalogued as COSV65878388; called by muse, mutect2
- ALOX12B | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 42/514 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs774946794, COSV59877269; called by muse, mutect2
- AP2B1 | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 48/652 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759031459; called by muse, mutect2
- CFAP46 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 25/822 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as rs1172444441, COSV100886472; called by muse, mutect2
- COL21A1 | c.2489C>A p.P830H | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99778791; called by muse, mutect2
- COQ8A | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 40/960 reads (4%) | catalogued as COSV100825820; called by muse, mutect2
- FLG | c.1676A>G p.H559R | Missense Mutation (SNP) | VAF 205/2256 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as rs546475787, COSV64240556; called by muse, mutect2
- GBE1 | c.1279G>T p.G427* | Nonsense Mutation (SNP) | VAF 42/824 reads (5%) | catalogued as CM121171, COSV70103391; called by muse, mutect2
- KRT84 | c.117G>C p.W39C | Missense Mutation (SNP) | VAF 54/1622 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV57771928; called by muse, mutect2
- ABCA4 | c.1341G>C p.Q447H | Missense Mutation (SNP) | VAF 42/762 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.375); called by muse, mutect2
- ADCYAP1R1 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 28/976 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2
- BRIP1 | c.1629-1G>C p.X543_splice | Splice Site (SNP) | VAF 29/847 reads (3%) | called by muse, mutect2
- C7 | c.1385A>T p.N462I | Missense Mutation (SNP) | VAF 19/495 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DBX2 | c.389A>T p.Q130L | Missense Mutation (SNP) | VAF 28/694 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.05); called by muse, mutect2
- EML4 | c.1382G>A p.C461Y | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- F11 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 42/1096 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); called by muse, mutect2
- FLG | c.10015C>A p.Q3339K | Missense Mutation (SNP) | VAF 91/1738 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2
- GABRA1 | c.-15-3C>T | Splice Region (SNP) | VAF 42/939 reads (4%) | called by muse, mutect2
- GNRHR | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 25/648 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2
- HSPG2 | c.11990C>A p.S3997* | Nonsense Mutation (SNP) | VAF 38/1071 reads (4%) | called by muse, mutect2
- KRTAP10-7 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 42/1236 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- LCK | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 34/771 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- MAEL | c.367C>A p.H123N | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); called by muse, mutect2
- MCHR2 | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MUC16 | c.5366A>T p.E1789V | Missense Mutation (SNP) | VAF 17/373 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2
- MYH2 | c.931T>A p.Y311N | Missense Mutation (SNP) | VAF 43/654 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- OR11L1 | c.830T>A p.F277Y | Missense Mutation (SNP) | VAF 24/779 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- PAPPA2 | c.1597T>A p.C533S | Missense Mutation (SNP) | VAF 26/814 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- PNPLA8 | c.1319G>C p.R440T | Missense Mutation (SNP) | VAF 44/864 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); called by muse, mutect2
- POU2AF1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 63/1332 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PROSER1 | c.2777C>T p.S926L | Missense Mutation (SNP) | VAF 22/676 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- RAET1G | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); called by muse, mutect2
- RNPS1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 13/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SMG6 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 56/1548 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2
- SRBD1 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.675); called by muse, mutect2
- TMPRSS6 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 32/701 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2
- TNKS1BP1 | c.3062A>G p.E1021G | Missense Mutation (SNP) | VAF 23/613 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- TSHB | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 29/834 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2
- UBE2NL | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 25/636 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- UBE2NL | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 24/626 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2
- ZNF169 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 29/624 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF366 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 23/751 reads (3%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- EDA2R | c.822G>A p.L274= | Silent (SNP) | VAF 24/248 reads (10%) | called by muse, mutect2
- FARS2 | c.1143C>T p.F381= | Silent (SNP) | VAF 24/896 reads (3%) | catalogued as COSV51166002, COSV51169053; called by muse, mutect2
- HSPG2 | c.12156C>G p.L4052= | Silent (SNP) | VAF 28/696 reads (4%) | called by muse, mutect2
- IL1RL1 | c.1453C>T p.L485= | Silent (SNP) | VAF 33/1080 reads (3%) | catalogued as rs1161183012; called by muse, mutect2
- KCNA5 | c.1089G>T p.V363= | Silent (SNP) | VAF 72/1418 reads (5%) | called by muse, mutect2
- KIF2B | c.1539C>T p.S513= | Silent (SNP) | VAF 26/858 reads (3%) | called by muse, mutect2
- LEMD2 | c.613C>A p.R205= | Silent (SNP) | VAF 36/508 reads (7%) | called by muse, mutect2
- MAF | c.324C>T p.F108= | Silent (SNP) | VAF 34/1016 reads (3%) | called by muse, mutect2
- NYX | c.1359C>T p.G453= | Silent (SNP) | VAF 14/260 reads (5%) | catalogued as rs1328519140; called by muse, mutect2
- POTEE | c.282C>G p.L94= | Silent (SNP) | VAF 46/1802 reads (3%) | called by muse, mutect2
- PRKCD | c.1155C>T p.V385= | Silent (SNP) | VAF 28/881 reads (3%) | called by muse, mutect2
- PTCHD4 | c.726G>T p.V242= | Silent (SNP) | VAF 33/779 reads (4%) | called by muse, mutect2
- RGS11 | c.625C>A p.R209= (on ENST00000397770 / NM_183337.3; = p.R188= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- SIGLEC1 | c.2034C>T p.N678= | Silent (SNP) | VAF 44/1012 reads (4%) | catalogued as rs1447778051; called by muse, mutect2
- SLC4A5 | c.2667C>T p.L889= | Silent (SNP) | VAF 76/1010 reads (8%) | called by muse, mutect2
- ZHX3 | c.1758C>T p.T586= | Silent (SNP) | VAF 25/678 reads (4%) | called by muse, mutect2
- ATP5PF | c.-98G>T | 5'UTR (SNP) | VAF 29/738 reads (4%) | called by muse, mutect2
- CXCL12 | c.*267T>A | 3'UTR (SNP) | VAF 27/782 reads (3%) | catalogued as rs1428901076; called by muse, mutect2
- DENND10P1 | n.1091G>A | RNA (SNP) | VAF 64/934 reads (7%) | called by muse, mutect2
- HSD17B1 | c.266-13C>G | Intron (SNP) | VAF 32/456 reads (7%) | called by muse, mutect2
- IGFN1 | c.1242-1665A>T | Intron (SNP) | VAF 17/312 reads (5%) | called by muse, mutect2
- MIF | c.281+34G>A | Intron (SNP) | VAF 17/289 reads (6%) | called by muse, mutect2
- SAE1 | c.-21G>T | 5'UTR (SNP) | VAF 19/459 reads (4%) | called by muse, mutect2
- UBL4A | c.*112G>C | 3'UTR (SNP) | VAF 16/316 reads (5%) | catalogued as rs1557212539; called by muse, mutect2
- UBL4A | c.*111G>T | 3'UTR (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
